Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8362, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8362-01A (Primary Tumor).

[page 1 of 4]
	Case ID	Gross Description	Microscopic Description

[page 2 of 4]
Diagnosis Details	Comments	Formatted Path Report
		STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Fundus Tumor size: 16 x 14 x 2 cm Tumor features: Exophytic (polypoid) Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Adjacent structures (specify) - Omentum Lymph nodes: 15/30 positive for metastasis (Intraabdominal 15/30) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 3 of 4]
	ID	Excision Date

[page 4 of 4]
Laterality

Source: NCI Genomic Data Commons file b337a74e-3a56-42fa-aa10-53f35a5493f5 (TCGA-BR-8362.73BE4302-C225-4C2C-B3F6-57644F9FABF8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).